Somatic mutation profile of tumor specimen MMRF_1533_2_BM_CD138pos (aliquot MMRF_1533_2_BM_CD138pos_T1_KHS5U_L11094) from MMRF case MMRF_1533, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 65.7 years (24,012 days).
Specimen MMRF_1533_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c828a8ce-1fe4-4c13-a551-8a281668a54b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1533_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1533_1_PB_Whole_C7_KBS5U_K11899; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7feca00c-1d2d-407a-926a-baad55f7e352

The open-access MAF lists 182 somatic variants for this specimen: 72 protein-altering or splice-affecting, 21 silent, 89 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 61, 3'UTR 44, Intron 28, Silent 21, 5'UTR 9, Splice Site 4, Nonsense Mutation 4, RNA 3, 5'Flank 3, 3'Flank 2, Splice Region 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA13 | c.12031C>T p.R4011W | Missense Mutation (SNP) | VAF 110/203 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772310771, COSV71292500; called by muse, mutect2, varscan2
- ACCSL | c.1633C>T p.R545W | Missense Mutation (SNP) | VAF 66/209 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.874); catalogued as rs752690708; called by muse, mutect2, varscan2
- CARS1 | c.26-3C>T | Splice Region (SNP) | VAF 21/159 reads (13%) | catalogued as rs769305325; called by muse, mutect2, varscan2
- CCDC92 | c.553G>A p.V185M | Missense Mutation (SNP) | VAF 55/106 reads (52%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.636); catalogued as rs375777447; called by muse, mutect2, varscan2
- CHAC2 | c.135+1G>A p.X45_splice | Splice Site (SNP) | VAF 50/89 reads (56%) | catalogued as rs1187677389; called by muse, mutect2, varscan2
- CRTC1 | c.382-1C>T p.X128_splice | Splice Site (SNP) | VAF 35/164 reads (21%) | catalogued as COSV58718306; called by muse, mutect2, varscan2
- DGKD | c.2263C>T p.L755= (on ENST00000264057 / NM_152879.3; = p.L711= on NM_003648.3 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 27/63 reads (43%) | catalogued as COSV51034518; called by muse, mutect2, varscan2
- DIO2 | c.97C>G p.L33V | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as COSV70445078; called by muse, mutect2, varscan2
- DNHD1 | c.65C>G p.S22C | Missense Mutation (SNP) | VAF 51/194 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.615); catalogued as rs760108684; called by muse, mutect2, varscan2
- EDRF1 | c.3620A>G p.N1207S (on ENST00000356792 / NM_001202438.2; = p.N1173S on NM_015608.2) | Missense Mutation (SNP) | VAF 18/184 reads (10%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as rs779140410; called by muse, mutect2
- FAM9B | c.487G>T p.V163L | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs146868808, COSV59120508; called by muse, mutect2, varscan2
- FPGS | c.1517C>A p.P506Q | Missense Mutation (SNP) | VAF 18/211 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as rs1325946824, COSV61227714; called by muse, mutect2
- GABBR2 | c.666G>T p.E222D | Missense Mutation (SNP) | VAF 44/121 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.396); catalogued as COSV99409330; called by muse, mutect2, varscan2
- GABPB1 | c.800C>T p.S267L | Missense Mutation (SNP) | VAF 10/318 reads (3%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.916); catalogued as rs1407115703; called by muse, mutect2
- GAD2 | c.326C>T p.A109V | Missense Mutation (SNP) | VAF 178/383 reads (46%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV52169605; called by muse, mutect2, varscan2
- H4C5 | c.81C>G p.I27M | Missense Mutation (SNP) | VAF 104/197 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV63486767; called by muse, mutect2, varscan2
- HTRA4 | c.208C>T p.R70C | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.786); catalogued as COSV56759872; called by muse, mutect2, varscan2
- LRRN4 | c.2146C>T p.R716C | Missense Mutation (SNP) | VAF 43/89 reads (48%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs756574056; called by muse, mutect2, varscan2
- LTBP4 | c.3370G>T p.E1124* (on ENST00000308370 / NM_001042544.1; = p.E1087* on NM_003573.2) | Nonsense Mutation (SNP) | VAF 20/90 reads (22%) | catalogued as COSV52578562; called by muse, mutect2, varscan2
- MAP7D2 | c.1206G>C p.K402N | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs770372208; called by muse, mutect2, varscan2
- MCC | c.2292T>A p.D764E | Missense Mutation (SNP) | VAF 17/141 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs756895312; called by muse, mutect2, varscan2
- MCF2L | c.1397C>T p.T466M (on ENST00000375608; = p.T434M on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs751741111, COSV65047726; called by muse, mutect2, varscan2
- MRC2 | c.3641C>T p.P1214L | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as rs554348769; called by muse, mutect2, varscan2
- NRXN1 | c.410G>T p.W137L | Missense Mutation (SNP) | VAF 114/237 reads (48%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as COSV68015937; called by muse, mutect2, varscan2
- PDE4D | c.2335C>T p.P779S (on ENST00000340635 / NM_001104631.2; = p.P643S on NM_006203.4) | Missense Mutation (SNP) | VAF 135/376 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.979); catalogued as COSV57720471; called by muse, mutect2, varscan2
- RBBP8NL | c.164A>C p.K55T | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV53350116; called by muse, mutect2, varscan2
- RFX7 | c.3642C>G p.F1214L (on ENST00000559447 / NM_001368074.1; = p.F1311L on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 129/256 reads (50%) | SIFT tolerated (0.36); PolyPhen benign (0.015); catalogued as COSV57965522; called by muse, mutect2, varscan2
- ROCK2 | c.3511G>A p.V1171I | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.334); catalogued as rs1231438319; called by muse, mutect2, varscan2
- RSPO4 | c.242G>A p.R81H | Missense Mutation (SNP) | VAF 48/78 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780874153, COSV54083503; called by muse, mutect2, varscan2
- SMN1 | c.850C>A p.Q284K | Missense Mutation (SNP) | VAF 65/277 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs1199331007, COSV100665254; called by muse, mutect2, varscan2
- STK33 | c.103C>A p.P35T | Missense Mutation (SNP) | VAF 214/934 reads (23%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.018); catalogued as COSV59398920; called by muse, mutect2, varscan2
- TUSC3 | c.445C>A p.P149T | Missense Mutation (SNP) | VAF 37/46 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65885329; called by muse, mutect2, varscan2
- VWF | c.6442G>C p.A2148P | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.958); catalogued as COSV54611913; called by muse, varscan2
- ZNF479 | c.488T>A p.V163D | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as rs541666980; called by muse, mutect2, varscan2
- ADRA2C | c.656T>G p.F219C | Missense Mutation (SNP) | VAF 153/303 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- APBB1 | c.1776C>G p.I592M | Missense Mutation (SNP) | VAF 18/365 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2
- ATP12A | c.579G>C p.K193N | Missense Mutation (SNP) | VAF 43/44 reads (98%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- CACHD1 | c.2194T>A p.Y732N | Missense Mutation (SNP) | VAF 85/188 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- CCDC168 | c.15434G>A p.R5145K | Missense Mutation (SNP) | VAF 73/177 reads (41%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- CHMP3 | c.101T>A p.I34K | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- DBNDD2 | c.352C>A p.Q118K | Missense Mutation (SNP) | VAF 100/177 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- DIAPH3 | c.2014A>T p.K672* (on ENST00000400324 / NM_001042517.2; = p.K409* on NM_030932.3) | Nonsense Mutation (SNP) | VAF 3/15 reads (20%) | called by muse, mutect2
- DOCK1 | c.2272C>T p.Q758* | Nonsense Mutation (SNP) | VAF 23/45 reads (51%) | called by mutect2, varscan2
- ENAM | c.1987G>A p.E663K | Missense Mutation (SNP) | VAF 60/133 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.652); called by muse, mutect2, varscan2
- FAM20C | c.1627C>A p.L543M | Missense Mutation (SNP) | VAF 47/84 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAM71F2 | c.887T>A p.V296D | Missense Mutation (SNP) | VAF 72/153 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- FAT3 | c.13504G>C p.V4502L | Missense Mutation (SNP) | VAF 131/343 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- GALNT10 | c.335G>T p.G112V | Missense Mutation (SNP) | VAF 63/227 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GALNT10 | c.1310G>A p.W437* | Nonsense Mutation (SNP) | VAF 70/266 reads (26%) | called by muse, mutect2, varscan2
- IFRD1 | c.285-2A>G p.X95_splice | Splice Site (SNP) | VAF 16/98 reads (16%) | called by muse, mutect2
- IL18R1 | c.1564G>T p.A522S | Missense Mutation (SNP) | VAF 76/160 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- LILRB2 | c.661G>A p.V221I | Missense Mutation (SNP) | VAF 33/161 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- MCC | c.2293C>A p.L765I | Missense Mutation (SNP) | VAF 17/138 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- METTL2B | c.274G>T p.D92Y | Missense Mutation (SNP) | VAF 100/233 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MUC5AC | c.14822A>T p.D4941V | Missense Mutation (SNP) | VAF 50/174 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MUSK | c.2426A>T p.E809V | Missense Mutation (SNP) | VAF 158/242 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYRFL | c.2378C>A p.S793Y | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- OR7A10 | c.397A>T p.M133L | Missense Mutation (SNP) | VAF 18/372 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); called by muse, mutect2
- PADI1 | c.1439T>C p.V480A | Missense Mutation (SNP) | VAF 71/156 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2
- PNPLA3 | c.132C>A p.F44L | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PRAMEF11 | c.1423C>A p.Q475K | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT tolerated (0.86); PolyPhen benign (0.106); called by muse, mutect2
- RALGPS2 | c.1019A>T p.K340M | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RASSF10 | c.626C>T p.S209F | Missense Mutation (SNP) | VAF 212/270 reads (79%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- SLITRK4 | c.2026A>T p.N676Y | Missense Mutation (SNP) | VAF 87/87 reads (100%) | SIFT tolerated (0.28); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- THAP9 | c.323T>C p.L108P | Missense Mutation (SNP) | VAF 49/74 reads (66%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- TMC2 | c.953C>A p.A318E | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- TRBV5-1 | c.192C>A p.F64L | Missense Mutation (SNP) | VAF 22/142 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- TRIT1 | c.1051G>T p.D351Y | Missense Mutation (SNP) | VAF 78/223 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); called by muse, mutect2, varscan2
- TTN | c.72703_72704insC p.V24235Afs*15 (on ENST00000591111; = p.V16811Afs*15 on NM_003319.4) | Frame Shift Ins (INS) | VAF 112/260 reads (43%) | called by mutect2, pindel, varscan2
- VPS54 | c.1009_1010+8del p.X337_splice | Splice Site (DEL) | VAF 37/78 reads (47%) | called by mutect2, pindel, varscan2
- ZAP70 | c.1684C>G p.P562A | Missense Mutation (SNP) | VAF 69/122 reads (57%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ZNF701 | c.109C>A p.Q37K | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- AFAP1 | c.2127C>G p.G709= | Silent (SNP) | VAF 15/40 reads (38%) | called by muse, mutect2, varscan2
- APOA4 | c.609C>A p.P203= | Silent (SNP) | VAF 113/374 reads (30%) | catalogued as COSV63361142, COSV63361244; called by muse, mutect2, varscan2
- C1orf159 | c.1059G>A p.P353= (on ENST00000379339 / NM_001330306.2; = p.P171= on NM_017891.5) | Silent (SNP) | VAF 74/155 reads (48%) | catalogued as rs532391088; called by muse, mutect2, varscan2
- CITED1 | c.540G>A p.Q180= | Silent (SNP) | VAF 40/224 reads (18%) | called by muse, mutect2, varscan2
- CNGB1 | c.3219G>A p.Q1073= | Silent (SNP) | VAF 11/50 reads (22%) | called by muse, mutect2, varscan2
- FGD3 | c.1854G>A p.E618= | Silent (SNP) | VAF 13/184 reads (7%) | called by muse, mutect2
- GRM6 | c.1767G>A p.P589= | Silent (SNP) | VAF 24/93 reads (26%) | catalogued as rs754267755, COSV51432343; called by muse, mutect2, varscan2
- HLX | c.1032C>T p.D344= | Silent (SNP) | VAF 46/137 reads (34%) | called by muse, mutect2, varscan2
- IGLV3-1 | c.294T>C p.A98= | Silent (SNP) | VAF 84/173 reads (49%) | catalogued as rs546240484; called by muse, mutect2, varscan2
- KCNAB3 | c.474C>G p.T158= | Silent (SNP) | VAF 59/62 reads (95%) | called by muse, mutect2, varscan2
- METTL6 | c.679C>T p.L227= | Silent (SNP) | VAF 111/169 reads (66%) | catalogued as rs1255279788; called by muse, mutect2, varscan2
- MMP13 | c.891A>G p.R297= | Silent (SNP) | VAF 9/236 reads (4%) | called by muse, mutect2
- NRIP3 | c.393C>G p.L131= | Silent (SNP) | VAF 68/293 reads (23%) | catalogued as COSV100487285; called by muse, mutect2, varscan2
- OR11L1 | c.21C>A p.S7= | Silent (SNP) | VAF 217/551 reads (39%) | called by muse, mutect2, varscan2
- PELI3 | c.348C>G p.V116= | Silent (SNP) | VAF 17/217 reads (8%) | called by muse, mutect2
- PLAA | c.357A>G p.S119= | Silent (SNP) | VAF 26/93 reads (28%) | catalogued as rs1251664115; called by muse, mutect2
- PRDM16 | c.1473C>A p.S491= | Silent (SNP) | VAF 22/283 reads (8%) | called by muse, mutect2
- RYR2 | c.2544C>T p.R848= | Silent (SNP) | VAF 63/154 reads (41%) | catalogued as rs748097250, COSV63683700; ClinVar: likely benign; called by muse, mutect2, varscan2
- SCN2A | c.2676C>T p.V892= | Silent (SNP) | VAF 10/174 reads (6%) | called by muse, mutect2
- SEMA3E | c.1389A>G p.V463= | Silent (SNP) | VAF 25/40 reads (63%) | called by muse, mutect2, varscan2
- SLC8A2 | c.765C>T p.Y255= | Silent (SNP) | VAF 49/137 reads (36%) | catalogued as rs1343377843; called by muse, mutect2, varscan2
- ABHD2 | c.*6677G>A | 3'UTR (SNP) | VAF 5/47 reads (11%) | called by muse, mutect2, varscan2
- ACADS | c.360+105C>T | Intron (SNP) | VAF 13/18 reads (72%) | called by muse, mutect2, varscan2
- ACTG2 | c.256-239T>G | Intron (SNP) | VAF 25/49 reads (51%) | called by muse, mutect2, varscan2
- ADAMTS2 | c.*2159A>T | 3'UTR (SNP) | VAF 22/347 reads (6%) | called by muse, mutect2
- ADAMTSL1 | c.4643+1015T>A | Intron (SNP) | VAF 6/82 reads (7%) | called by muse, mutect2
- ADD3-AS1 | chr10:109941610 C>A | 3'Flank (SNP) | VAF 130/244 reads (53%) | called by muse, mutect2, varscan2
- ADORA1 | c.*1353G>C | 3'UTR (SNP) | VAF 6/25 reads (24%) | called by muse, mutect2, varscan2
- AJAP1 | c.*5460T>G | 3'UTR (SNP) | VAF 51/106 reads (48%) | called by muse, mutect2, varscan2
- ALG5 | c.66+79C>T | Intron (SNP) | VAF 24/25 reads (96%) | called by muse, mutect2, varscan2
- AMER3 | c.*2218C>T | 3'UTR (SNP) | VAF 106/234 reads (45%) | catalogued as rs1172287605; called by muse, mutect2, varscan2
- BMP6 | c.*767_*815del | 3'UTR (DEL) | VAF 29/100 reads (29%) | called by mutect2, pindel
- BTBD9 | c.*4760C>A | 3'UTR (SNP) | VAF 30/66 reads (45%) | called by muse, mutect2, varscan2
- C11orf45 | c.-6G>A | 5'UTR (SNP) | VAF 87/313 reads (28%) | catalogued as rs368037087; called by muse, mutect2, varscan2
- C18orf54 | c.589+271A>T | Intron (SNP) | VAF 17/166 reads (10%) | called by muse, mutect2, varscan2
- CATSPERG | c.2094+58G>T | Intron (SNP) | VAF 17/99 reads (17%) | called by muse, mutect2, varscan2
- CATSPERG | c.2931-51T>G | Intron (SNP) | VAF 69/185 reads (37%) | called by muse, mutect2, varscan2
- CD1E | c.-16C>G | 5'UTR (SNP) | VAF 141/263 reads (54%) | catalogued as COSV100937020, COSV63770007; called by muse, mutect2, varscan2
- CFAP57 | c.1929+698T>A | Intron (SNP) | VAF 9/14 reads (64%) | called by muse, mutect2, varscan2
- CFAP65 | c.542+1176T>C | Intron (SNP) | VAF 12/146 reads (8%) | called by muse, mutect2
- CHST15 | c.-317T>G | 5'UTR (SNP) | VAF 22/51 reads (43%) | catalogued as rs1425036697; called by muse, mutect2, varscan2
- CLSPN | c.3042+101C>T | Intron (SNP) | VAF 21/161 reads (13%) | called by muse, mutect2, varscan2
- CRYBG3 | c.*1075T>A | 3'UTR (SNP) | VAF 12/159 reads (8%) | called by muse, mutect2
- DHFR2 | c.*1612G>T | 3'UTR (SNP) | VAF 36/122 reads (30%) | called by muse, mutect2, varscan2
- DOCK5 | c.-34T>G | 5'UTR (SNP) | VAF 13/13 reads (100%) | called by muse, mutect2, varscan2
- DTWD2 | c.*2398A>G | 3'UTR (SNP) | VAF 5/18 reads (28%) | catalogued as COSV58366270; called by muse, mutect2, varscan2
- DUSP18 | c.*448A>T | 3'UTR (SNP) | VAF 60/109 reads (55%) | called by muse, mutect2, varscan2
- EIF4E3 | c.*5231G>A | 3'UTR (SNP) | VAF 68/212 reads (32%) | called by muse, mutect2, varscan2
- FAM107A | c.*2125A>G | 3'UTR (SNP) | VAF 39/136 reads (29%) | catalogued as rs1349617536; called by muse, mutect2, varscan2
- FAM111A | c.*1373C>T | 3'UTR (SNP) | VAF 15/47 reads (32%) | called by muse, mutect2, varscan2
- FHIT | c.*269T>A | 3'UTR (SNP) | VAF 7/114 reads (6%) | called by muse, mutect2
- GFM1 | c.*540G>A | 3'UTR (SNP) | VAF 26/70 reads (37%) | catalogued as rs1286858921; called by muse, mutect2, varscan2
- GNB1L | c.*3739G>T | 3'UTR (SNP) | VAF 47/106 reads (44%) | called by muse, mutect2, varscan2
- GPR61 | chr1:109546685 T>G | 3'Flank (SNP) | VAF 29/75 reads (39%) | called by muse, mutect2, varscan2
- GRAMD1B | c.*4885C>A | 3'UTR (SNP) | VAF 59/189 reads (31%) | called by muse, mutect2, varscan2
- IGHD1-1 | chr14:105922626 T>C | 5'Flank (SNP) | VAF 172/173 reads (99%) | called by muse, mutect2, varscan2
- IGKV1-33 | c.-24A>G | 5'UTR (SNP) | VAF 8/18 reads (44%) | called by muse, varscan2
- IL1RL1 | c.971-2163G>T | Intron (SNP) | VAF 10/31 reads (32%) | called by muse, mutect2, varscan2
- ING3 | c.267+226_267+227insCGGTAACA | Intron (INS) | VAF 46/105 reads (44%) | called by mutect2, varscan2*
- JAG2 | c.*1288C>A | 3'UTR (SNP) | VAF 72/74 reads (97%) | called by muse, mutect2, varscan2
- KIAA1549 | c.*2898T>G | 3'UTR (SNP) | VAF 37/67 reads (55%) | called by muse, mutect2, varscan2
- LAMTOR3 | c.*2503G>C | 3'UTR (SNP) | VAF 25/81 reads (31%) | called by muse, mutect2, varscan2
- LDHB | c.714-134G>C | Intron (SNP) | VAF 6/11 reads (55%) | called by mutect2, varscan2
- LINC00243 | n.689A>G | RNA (SNP) | VAF 50/115 reads (43%) | called by muse, mutect2, varscan2
- MAGI3 | c.553+20C>T | Intron (SNP) | VAF 31/78 reads (40%) | catalogued as rs760170611; called by muse, mutect2, varscan2
- MTURN | c.*1624A>T | 3'UTR (SNP) | VAF 15/35 reads (43%) | called by muse, mutect2, varscan2
- NIBAN2 | c.*1233G>A | 3'UTR (SNP) | VAF 89/129 reads (69%) | called by muse, mutect2, varscan2
- NKX2-5 | c.335-276A>T | Intron (SNP) | VAF 31/137 reads (23%) | called by muse, mutect2, varscan2
- NPR2 | c.*283G>T | 3'UTR (SNP) | VAF 183/584 reads (31%) | called by muse, mutect2, varscan2
- NRIP3 | c.*504C>G | 3'UTR (SNP) | VAF 37/342 reads (11%) | called by muse, mutect2, varscan2
- NUMA1 | c.1242+13A>G | Intron (SNP) | VAF 15/48 reads (31%) | called by mutect2, varscan2
- PDE4D | c.*498G>A | 3'UTR (SNP) | VAF 26/108 reads (24%) | called by muse, mutect2, varscan2
- PDP1 | c.-149G>C | 5'UTR (SNP) | VAF 41/80 reads (51%) | called by muse, mutect2, varscan2
- PHLDB2 | c.1719+459T>C | Intron (SNP) | VAF 71/81 reads (88%) | called by muse, mutect2, varscan2
- PLA2G2F | c.*1801C>T | 3'UTR (SNP) | VAF 68/138 reads (49%) | catalogued as rs568315189, COSV64280259; called by muse, mutect2, varscan2
- PLA2R1 | c.*3703T>G | 3'UTR (SNP) | VAF 42/113 reads (37%) | called by muse, mutect2, varscan2
- PLEKHG5 | c.1393-39C>T | Intron (SNP) | VAF 11/17 reads (65%) | catalogued as rs1300151068; called by muse, mutect2, varscan2
- POLRMT | c.*43C>T | 3'UTR (SNP) | VAF 7/56 reads (13%) | catalogued as rs769996691; called by mutect2, varscan2
- POU5F1B | c.*471G>A | 3'UTR (SNP) | VAF 20/67 reads (30%) | catalogued as rs1029678732; called by muse, mutect2, varscan2
- PSAP | c.1351-44G>A | Intron (SNP) | VAF 74/173 reads (43%) | catalogued as rs536532228; called by muse, mutect2, varscan2
- PSMD2 | c.135+41G>T | Intron (SNP) | VAF 9/25 reads (36%) | called by muse, mutect2, varscan2
- RIMS4 | c.*2964A>G | 3'UTR (SNP) | VAF 34/89 reads (38%) | called by muse, mutect2, varscan2
- RNF40 | c.*1369C>G | 3'UTR (SNP) | VAF 72/660 reads (11%) | called by muse, mutect2
- RUNX1T1 | c.1280-3945C>T | Intron (SNP) | VAF 36/65 reads (55%) | catalogued as rs996073184; called by muse, mutect2, varscan2
- SBK1 | c.*455A>G | 3'UTR (SNP) | VAF 74/190 reads (39%) | called by muse, mutect2, varscan2
- SCAF4 | c.-383C>G | 5'UTR (SNP) | VAF 28/93 reads (30%) | catalogued as rs1212484489; called by muse, mutect2, varscan2
- SCUBE2 | c.*320C>G | 3'UTR (SNP) | VAF 27/304 reads (9%) | catalogued as COSV58543844; called by muse, mutect2
- SHROOM3 | c.*498G>C | 3'UTR (SNP) | VAF 16/58 reads (28%) | called by muse, mutect2, varscan2
- SLC12A1 | c.725-648C>A | Intron (SNP) | VAF 18/38 reads (47%) | called by muse, mutect2, varscan2
- SLC25A13 | c.*456A>G | 3'UTR (SNP) | VAF 13/30 reads (43%) | catalogued as rs766684721; called by muse, mutect2, varscan2
- SLC26A8 | c.*154C>T | 3'UTR (SNP) | VAF 46/102 reads (45%) | catalogued as rs1000524052; called by muse, mutect2, varscan2
- SLC45A1 | c.*56C>A | 3'UTR (SNP) | VAF 44/71 reads (62%) | called by muse, mutect2, varscan2
- SLC6A3 | c.*1596G>T | 3'UTR (SNP) | VAF 72/190 reads (38%) | called by muse, mutect2, varscan2
- SMAP1 | chr6:70667818 C>A | 5'Flank (SNP) | VAF 15/24 reads (63%) | called by muse, mutect2, varscan2
- SNX29 | c.1124+346G>T | Intron (SNP) | VAF 134/320 reads (42%) | called by muse, varscan2
- SOBP | c.-315G>A | 5'UTR (SNP) | VAF 46/96 reads (48%) | called by muse, varscan2
- ST6GALNAC2 | c.-45C>A | 5'UTR (SNP) | VAF 19/37 reads (51%) | called by muse, mutect2, varscan2
- STEAP1B | chr7:22500257 G>A | 5'Flank (SNP) | VAF 7/14 reads (50%) | called by muse, mutect2
- TDGF1P3 | n.789C>T | RNA (SNP) | VAF 123/135 reads (91%) | called by muse, mutect2, varscan2
- TEDDM1 | c.*829T>A | 3'UTR (SNP) | VAF 28/90 reads (31%) | called by muse, mutect2, varscan2
- TMEM263 | c.*1361T>C | 3'UTR (SNP) | VAF 43/90 reads (48%) | called by muse, mutect2, varscan2
- TMEM50B | c.*538G>A | 3'UTR (SNP) | VAF 8/21 reads (38%) | called by mutect2, varscan2
- TTC22 | c.1020+576A>G | Intron (SNP) | VAF 46/84 reads (55%) | called by muse, mutect2, varscan2
- UBE2E3 | c.195-31T>A | Intron (SNP) | VAF 22/46 reads (48%) | called by muse, mutect2, varscan2
- YPEL4 | c.185+18C>T | Intron (SNP) | VAF 91/339 reads (27%) | called by muse, mutect2, varscan2
- ZCCHC24 | c.*794A>G | 3'UTR (SNP) | VAF 35/82 reads (43%) | called by muse, mutect2, varscan2
- ZNF681 | c.*321C>T | 3'UTR (SNP) | VAF 6/122 reads (5%) | called by muse, mutect2
- ZNF780A | c.-46+848_-46+851del | Intron (DEL) | VAF 54/152 reads (36%) | catalogued as rs1366712145; called by pindel, varscan2
- ZNF812P | n.1166C>T | RNA (SNP) | VAF 20/486 reads (4%) | called by muse, mutect2
- ZSCAN18 | c.49+10G>A | Intron (SNP) | VAF 78/252 reads (31%) | called by muse, mutect2, varscan2
